Somatic mutation profile of tumor specimen TCGA-G9-A9S7-01A (aliquot TCGA-G9-A9S7-01A-11D-A41K-08) from TCGA case TCGA-G9-A9S7, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.3 years (20,213 days).
Specimen TCGA-G9-A9S7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fbc6c1e-57a7-4ee0-939e-968805170380.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-A9S7-10A (Blood Derived Normal), aliquot TCGA-G9-A9S7-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d9c26ab-954c-4439-a4c7-40ba00c8aa38

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 17, Silent 5, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM23 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.133); catalogued as rs377327401; called by muse, mutect2, varscan2
- CLDN16 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1480328199, COSV99290043; called by muse, mutect2, varscan2
- DNAJC19 | c.237A>C p.R79S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100700155; called by muse, mutect2, varscan2
- DTX3L | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs763580441, COSV56145703; called by muse, mutect2, varscan2
- HS6ST1 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs764697760, COSV52130194; called by muse, mutect2, varscan2
- IFT88 | c.2203-1G>A p.X735_splice (on ENST00000319980 / NM_001318493.2; = p.X726_splice on NM_006531.5 and 9 other RefSeq transcripts) | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as rs1198202638, COSV100179527; called by muse, mutect2, varscan2
- MARF1 | c.3496C>T p.R1166C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780016235, COSV100705682; called by muse, mutect2, varscan2
- NRXN3 | c.923A>C p.D308A (on ENST00000557594 / NM_001272020.2; = p.D940A on NM_004796.6) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV99816941; called by muse, mutect2, varscan2
- PAN3 | c.1885C>G p.R629G | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56705398, COSV99144623; called by muse, mutect2, varscan2
- PARP16 | c.893T>A p.L298Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99975360; called by muse, mutect2
- PAX5 | c.460T>C p.S154P | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.91); catalogued as COSV100814105; called by muse, mutect2, varscan2
- PCDHA8 | c.2112C>G p.I704M | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as COSV100969228; called by muse, mutect2, varscan2
- PNRC1 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.121); catalogued as rs763530301, COSV100259834; called by muse, varscan2
- PRKCZ | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.091); catalogued as COSV101057565, COSV66067938; called by muse, mutect2, varscan2
- RSPH10B2 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 49/278 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV99786041; called by muse, mutect2, varscan2
- SCAF8 | c.457G>C p.A153P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100913991; called by muse, mutect2, varscan2
- TNPO3 | c.264C>G p.D88E | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV99602655; called by muse, mutect2
- UBR4 | c.7574C>G p.S2525C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV100920587; called by muse, mutect2, varscan2
- HIPK1 | c.2172G>A p.A724= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs747522003, COSV100478666; called by muse, mutect2, varscan2
- NKD2 | c.948C>T p.A316= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs915859809, COSV99723900; called by muse, mutect2
- PICK1 | c.672T>A p.L224= | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as COSV100811058; called by muse, mutect2, varscan2
- TFAP2B | c.867A>G p.E289= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV99539797; called by muse, mutect2, varscan2
- TGIF2LY | c.9C>G p.A3= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100339628; called by muse, mutect2
